Somatic mutation profile of cancer-model specimen HCM-STAN-1113-C18-85B (3D Organoid, passage 7; aliquot HCM-STAN-1113-C18-85B-01D-A937-36), derived from the primary tumor of HCMI case HCM-STAN-1113-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 68.9 years (25,168 days).
Specimen HCM-STAN-1113-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f906cd3-22f3-4973-a685-780f12bb51d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-1113-C18-11A (Solid Tissue Normal), aliquot HCM-STAN-1113-C18-11A-04D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84e56cb6-51e0-407e-88c5-ff79c2b4aa4f

The open-access MAF lists 194 somatic variants for this specimen: 135 protein-altering or splice-affecting, 56 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 56, Nonsense Mutation 10, Frame Shift Del 4, 5'Flank 2, Splice Region 2, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 97/341 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 97/339 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 107/368 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.13458T>G p.I4486M | Missense Mutation (SNP) | VAF 266/268 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs768679977; called by muse, mutect2, varscan2
- AL645922.1 | c.2157del p.C720Afs*21 | Frame Shift Del (DEL) | VAF 278/404 reads (69%) | catalogued as COSV54959013; called by mutect2, varscan2
- AP4B1 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 235/236 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1427848579; called by muse, mutect2, varscan2
- APBA2 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1441180683, COSV68794088; called by muse, mutect2, varscan2
- ARMC4 | c.1046G>T p.R349M | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV53462778; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 168/654 reads (26%) | catalogued as COSV63438584; called by muse, mutect2, varscan2
- ASB5 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 120/376 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs768506681, COSV56672361, COSV99641542; called by muse, mutect2, varscan2
- ASMTL | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 413/782 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs745929353; called by muse, mutect2, varscan2
- ATCAY | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 365/513 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs753265304, COSV56659243; called by muse, mutect2, varscan2
- BNC2 | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 64/485 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs747242368, COSV66148430; called by muse, mutect2, varscan2
- BRD4 | c.3576G>A p.K1192= | Splice Region (SNP) | VAF 183/374 reads (49%) | catalogued as COSV99650096; called by muse, mutect2, varscan2
- BRWD3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as rs1057521931, COSV64745244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTG2 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 185/729 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104392379; called by muse, mutect2, varscan2
- CARS2 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 223/687 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV57284777; called by muse, mutect2, varscan2
- CDH23 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 179/526 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1064796283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDS2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 89/540 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66896521; called by muse, mutect2, varscan2
- CFAP65 | c.2744G>T p.W915L | Missense Mutation (SNP) | VAF 325/660 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100445409; called by muse, mutect2, varscan2
- CNMD | c.75G>A p.A25= | Splice Region (SNP) | VAF 121/360 reads (34%) | catalogued as rs1242035496; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 94/408 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, varscan2
- COL23A1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs780431788, COSV101177977; called by muse, mutect2, varscan2
- CSMD1 | c.9886G>A p.G3296S (on ENST00000520002; = p.G3295S on NM_033225.6) | Missense Mutation (SNP) | VAF 116/532 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757638862, COSV100145033; called by muse, mutect2, varscan2
- CTNND2 | c.3269A>G p.Y1090C | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1214249938; called by muse, mutect2, varscan2
- CUL7 | c.352A>C p.I118L | Missense Mutation (SNP) | VAF 185/519 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs1314580995; called by muse, mutect2, varscan2
- DIAPH2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 223/479 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779897805; called by muse, mutect2, varscan2
- DLGAP3 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs766267134, COSV52392724; called by muse, mutect2, varscan2
- DOP1A | c.6455G>A p.R2152H | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1187215002; called by muse, mutect2, varscan2
- FAT4 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 35/634 reads (6%) | catalogued as COSV67883474; called by muse, mutect2
- FBLN1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 125/433 reads (29%) | catalogued as rs1169120464; called by muse, mutect2, varscan2
- FRMPD1 | c.3661G>A p.V1221I | Missense Mutation (SNP) | VAF 139/436 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs200892375; called by muse, mutect2, varscan2
- FRMPD3 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 257/580 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as rs747111514, COSV52190816; called by muse, mutect2, varscan2
- FSIP2 | c.6247C>T p.R2083* | Nonsense Mutation (SNP) | VAF 86/438 reads (20%) | catalogued as rs758314634, COSV58079688; called by muse, mutect2, varscan2
- GALNT9 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 156/479 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100202059; called by muse, mutect2, varscan2
- GMPS | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV55812251; called by muse, mutect2, varscan2
- ICAM5 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 160/697 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV55748695; called by muse, mutect2, varscan2
- IGHG4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 158/1394 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs763568423; called by muse, mutect2, varscan2
- ITPR1 | c.4612C>T p.R1538W (on ENST00000354582; = p.R1523W on NM_002222.7) | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs765591834, COSV56975681; called by muse, mutect2, varscan2
- KIF20B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99590593; called by muse, mutect2, varscan2
- KRT37 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 25/928 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1318079805; called by muse, mutect2
- MAGEC2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 376/810 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV56001479; called by muse, mutect2, varscan2
- MAML3 | c.2938G>C p.G980R | Missense Mutation (SNP) | VAF 342/535 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV72208473; called by muse, mutect2, varscan2
- MMP28 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 174/825 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs370540313; called by muse, mutect2, varscan2
- MSGN1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 59/741 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV55263497; called by muse, mutect2
- NR3C1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 356/356 reads (100%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as rs1460349075; called by muse, varscan2
- NRXN1 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs749913654, COSV58444299; called by muse, mutect2, varscan2
- NUBP2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 166/511 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as rs749827351; called by muse, mutect2, varscan2
- OR51V1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs774588813, COSV58315645; called by muse, varscan2
- OTOA | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 156/516 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs777719065; called by muse, mutect2, varscan2
- OTOGL | c.5015G>C p.R1672P (on ENST00000547103; = p.R1663P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100086838, COSV100087488; called by muse, mutect2, varscan2
- PCDH17 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.787); catalogued as COSV100931455; called by muse, mutect2, varscan2
- PCDHA10 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 158/522 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56490353; called by muse, mutect2, varscan2
- PCDHB5 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 248/706 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1307227233, COSV50647275; called by muse, varscan2
- PDGFB | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58648431; called by muse, mutect2, varscan2
- PIK3CG | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 367/711 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63248254; called by muse, mutect2, varscan2
- PMS1 | c.2342G>A p.S781N | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV59715190; called by muse, mutect2
- PRDM8 | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 111/359 reads (31%) | catalogued as COSV60203539; called by muse, mutect2, varscan2
- PRR32 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 206/784 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs1412006452; called by muse, varscan2
- PRR32 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 203/796 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs887535258, COSV64420781; called by muse, varscan2
- PRRG1 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 97/514 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101068995, COSV66157819; called by muse, mutect2, varscan2
- PTPRN | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as COSV55350443; called by muse, mutect2, varscan2
- RNF150 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 131/448 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60800961; called by muse, mutect2, varscan2
- RSBN1 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs748962265; called by muse, mutect2, varscan2
- RYR2 | c.3089C>T p.P1030L | Missense Mutation (SNP) | VAF 96/418 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1404965456; ClinVar: uncertain significance; called by muse, varscan2
- S100A10 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 122/545 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV64290942; called by muse, mutect2, varscan2
- SH3BGRL | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 172/615 reads (28%) | catalogued as COSV100943503, COSV64621017, COSV64621276; called by muse, mutect2, varscan2
- SLC26A11 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 274/607 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs141463339; called by muse, mutect2, varscan2
- SLC5A2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 177/542 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs564929531; called by muse, mutect2, varscan2
- SLC5A5 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 122/556 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55831934; called by muse, varscan2
- SLCO1A2 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753971254; called by muse, varscan2
- SPDYE4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as rs569077736; called by muse, mutect2, varscan2
- STRN | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs200449462, COSV55752953; called by muse, mutect2, varscan2
- SVEP1 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 162/503 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs548514380, COSV57027534; called by muse, mutect2, varscan2
- TACR1 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 274/565 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537616; called by muse, mutect2, varscan2
- TENM1 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 185/750 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778994121, COSV64432201, COSV64439008; called by muse, mutect2, varscan2
- THSD7A | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 173/410 reads (42%) | catalogued as rs777727562, COSV69855816; called by muse, varscan2
- TMEM11 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 173/721 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV58313231; called by muse, mutect2, varscan2
- TNXB | c.9553G>A p.A3185T (on ENST00000647633; = p.A2938T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/410 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs780721675, COSV64488384; called by muse, mutect2, varscan2
- URB2 | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 290/596 reads (49%) | catalogued as rs540815059; called by muse, mutect2, varscan2
- WDR91 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 178/700 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs745637947, COSV60368508; called by muse, mutect2, varscan2
- YTHDF1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 164/1066 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757745929; called by muse, mutect2, varscan2
- ZNF330 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764846328; called by muse, mutect2, varscan2
- ZNF543 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 250/565 reads (44%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.971); catalogued as rs771063500, COSV58629268; called by muse, mutect2, varscan2
- ZNF865 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 182/751 reads (24%) | SIFT deleterious (0.03); catalogued as rs781501689; called by muse, mutect2, varscan2
- ACOX2 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 135/425 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGPAT3 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AVIL | c.2003A>G p.K668R | Missense Mutation (SNP) | VAF 123/412 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BAIAP3 | c.1571del p.P524Lfs*15 | Frame Shift Del (DEL) | VAF 105/340 reads (31%) | called by mutect2, varscan2
- C1orf35 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 151/647 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC169 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- COPE | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 185/749 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DMRTC2 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 98/463 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ELOVL2 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FOLR1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 151/457 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GPC3 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 301/620 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR20 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 475/976 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC2 | c.2207A>C p.N736T | Missense Mutation (SNP) | VAF 201/547 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HHIP | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IRF2BP2 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 264/564 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- IRF2BPL | c.1052_1062del p.A351Gfs*68 | Frame Shift Del (DEL) | VAF 256/452 reads (57%) | called by mutect2, varscan2
- ITGB5 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- JAKMIP3 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA3 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 370/370 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHDRBS3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- LRRC31 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LRRK1 | c.4081A>G p.M1361V | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MAML3 | c.2939G>C p.G980A | Missense Mutation (SNP) | VAF 342/535 reads (64%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAN1A2 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAP3K14 | c.2419G>C p.D807H | Missense Mutation (SNP) | VAF 203/394 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MDH1B | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 202/401 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MFAP3L | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 146/464 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MFSD8 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MIPOL1 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 110/353 reads (31%) | called by muse, mutect2, varscan2
- NBPF14 | c.8516C>T p.P2839L | Missense Mutation (SNP) | VAF 113/687 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCBP1 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 94/318 reads (30%) | called by muse, mutect2
- PGR | c.2777A>C p.K926T | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PHF2 | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PHF2 | c.641A>T p.K214I | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- PTPRT | c.799T>G p.C267G | Missense Mutation (SNP) | VAF 583/825 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGMB | c.362G>A p.C121Y (on ENST00000513185 / NM_001366508.1; = p.C162Y on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 476/476 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5B | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 345/547 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); called by muse, varscan2
- SLC20A2 | c.1658G>C p.R553T | Missense Mutation (SNP) | VAF 77/602 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SLC7A13 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 97/428 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNW1 | c.1149T>G p.N383K | Missense Mutation (SNP) | VAF 152/234 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SRRT | c.1070G>A p.S357N | Missense Mutation (SNP) | VAF 38/650 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- STRN | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 291/646 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYN2 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TAAR8 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 233/388 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TGIF1 | c.308_309dup p.E104Wfs*4 (on ENST00000330513 / NM_001374396.1; = p.E124Wfs*4 on NM_003244.4) | Frame Shift Ins (INS) | VAF 227/242 reads (94%) | called by mutect2, varscan2
- TMEM132C | c.920T>G p.V307G | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); called by muse, mutect2
- UNC13C | c.1689T>G p.D563E | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UVRAG | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2
- ZNF534 | c.547dup p.S183Ffs*13 (on ENST00000332323 / NM_001143939.3; = p.S170Ffs*13 on NM_001143938.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 89/344 reads (26%) | called by mutect2, varscan2
- ZNF687 | c.175del p.A59Lfs*23 | Frame Shift Del (DEL) | VAF 325/646 reads (50%) | called by mutect2, varscan2
- ACE | c.996C>T p.S332= | Silent (SNP) | VAF 321/651 reads (49%) | catalogued as rs767127845, COSV52006685; called by muse, mutect2, varscan2
- ADAM12 | c.2421G>A p.L807= | Silent (SNP) | VAF 166/461 reads (36%) | catalogued as COSV64134379; called by muse, mutect2, varscan2
- ADCY5 | c.2616C>T p.S872= | Silent (SNP) | VAF 116/470 reads (25%) | catalogued as rs766902305, COSV100567124; called by muse, mutect2, varscan2
- ADH1B | c.810C>T p.I270= | Silent (SNP) | VAF 109/386 reads (28%) | catalogued as rs904388509; called by muse, varscan2
- ANK1 | c.4579C>T p.L1527= | Silent (SNP) | VAF 111/515 reads (22%) | called by muse, mutect2, varscan2
- BASP1 | c.513C>T p.D171= | Silent (SNP) | VAF 163/513 reads (32%) | called by muse, mutect2, varscan2
- CBLB | c.2574C>G p.P858= | Silent (SNP) | VAF 76/258 reads (29%) | called by muse, mutect2, varscan2
- CELF6 | c.1041C>T p.P347= | Silent (SNP) | VAF 95/535 reads (18%) | catalogued as rs1047976329; called by muse, mutect2, varscan2
- CLIP3 | c.393C>T p.H131= | Silent (SNP) | VAF 174/333 reads (52%) | catalogued as rs767475996; called by muse, mutect2, varscan2
- COL4A1 | c.3645G>A p.P1215= | Silent (SNP) | VAF 228/620 reads (37%) | catalogued as rs765336200, COSV65422256; called by muse, mutect2, varscan2
- CTNND2 | c.777G>T p.L259= | Silent (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- EGF | c.252T>C p.N84= | Silent (SNP) | VAF 133/355 reads (37%) | catalogued as rs750616729; called by muse, mutect2, varscan2
- EPHA3 | c.1782G>A p.R594= | Silent (SNP) | VAF 114/291 reads (39%) | called by muse, mutect2, varscan2
- EPHB6 | c.1974C>T p.A658= | Silent (SNP) | VAF 130/584 reads (22%) | called by muse, varscan2
- GCNT1 | c.1230C>T p.A410= | Silent (SNP) | VAF 67/455 reads (15%) | catalogued as rs1277233343; called by muse, mutect2, varscan2
- GLI2 | c.2661G>A p.P887= (on ENST00000361492 / NM_001374353.1; = p.P904= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 219/802 reads (27%) | catalogued as rs1053909489; called by muse, mutect2, varscan2
- GRIP2 | c.312G>T p.R104= (on ENST00000619221; = p.R7= on NM_001080423.4) | Silent (SNP) | VAF 132/408 reads (32%) | called by muse, mutect2, varscan2
- KCNH3 | c.2766G>A p.S922= | Silent (SNP) | VAF 166/519 reads (32%) | catalogued as rs140591831; called by muse, mutect2, varscan2
- KSR2 | c.864G>A p.P288= | Silent (SNP) | VAF 188/566 reads (33%) | catalogued as rs771169274, COSV60393836; called by muse, mutect2, varscan2
- LRRC8E | c.1875C>T p.S625= | Silent (SNP) | VAF 289/590 reads (49%) | called by muse, mutect2, varscan2
- MAP3K10 | c.936G>A p.A312= | Silent (SNP) | VAF 120/576 reads (21%) | catalogued as rs748129608; called by muse, varscan2
- MAP3K7CL | c.723G>A p.S241= | Silent (SNP) | VAF 69/216 reads (32%) | catalogued as rs767209465; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1182C>T p.I394= | Silent (SNP) | VAF 85/302 reads (28%) | catalogued as rs769496083; called by muse, mutect2, varscan2
- MN1 | c.3720C>T p.D1240= | Silent (SNP) | VAF 145/417 reads (35%) | catalogued as COSV56558967; called by muse, mutect2, varscan2
- MUC16 | c.10425C>A p.T3475= | Silent (SNP) | VAF 124/596 reads (21%) | catalogued as COSV101199136; called by muse, mutect2, varscan2
- MUC5B | c.14118C>T p.T4706= | Silent (SNP) | VAF 249/710 reads (35%) | called by muse, mutect2, varscan2
- MUC6 | c.6531G>C p.S2177= | Silent (SNP) | VAF 268/802 reads (33%) | catalogued as COSV101424385, COSV70145016; called by muse, mutect2, varscan2
- NDST3 | c.1983C>T p.T661= | Silent (SNP) | VAF 63/298 reads (21%) | catalogued as rs1446469120; called by muse, mutect2, varscan2
- PCDHA7 | c.2307C>T p.L769= | Silent (SNP) | VAF 122/402 reads (30%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1617G>A p.P539= | Silent (SNP) | VAF 301/1081 reads (28%) | catalogued as rs1251485802; called by muse, mutect2, varscan2
- POLR2H | c.342G>A p.A114= | Silent (SNP) | VAF 155/469 reads (33%) | catalogued as rs202151346, COSV52615447; called by muse, mutect2, varscan2
- PSMB7 | c.777C>A p.I259= | Silent (SNP) | VAF 108/349 reads (31%) | called by muse, mutect2, varscan2
- PTPN9 | c.1170A>G p.V390= | Silent (SNP) | VAF 218/364 reads (60%) | catalogued as rs763844646; called by muse, mutect2, varscan2
- PTPRS | c.315C>T p.Y105= | Silent (SNP) | VAF 155/618 reads (25%) | catalogued as rs1232998256; called by muse, mutect2, varscan2
- RASAL1 | c.375G>A p.Q125= | Silent (SNP) | VAF 159/491 reads (32%) | catalogued as COSV55658357; called by muse, mutect2, varscan2
- RBMXL3 | c.609C>T p.P203= | Silent (SNP) | VAF 183/879 reads (21%) | called by muse, mutect2, varscan2
- RTP2 | c.240C>T p.R80= | Silent (SNP) | VAF 142/498 reads (29%) | catalogued as rs1428483091, COSV64078743, COSV64079249; called by muse, mutect2, varscan2
- SCN3A | c.4245A>C p.T1415= | Silent (SNP) | VAF 69/296 reads (23%) | called by muse, mutect2, varscan2
- SLC17A6 | c.1296T>G p.V432= | Silent (SNP) | VAF 81/211 reads (38%) | called by muse, mutect2, varscan2
- SLC38A9 | c.1372T>C p.L458= | Silent (SNP) | VAF 120/406 reads (30%) | called by muse, mutect2, varscan2
- SRPX | c.771A>G p.V257= | Silent (SNP) | VAF 76/399 reads (19%) | called by muse, mutect2, varscan2
- STPG2 | c.703C>T p.L235= | Silent (SNP) | VAF 111/377 reads (29%) | catalogued as rs1414849290; called by muse, mutect2, varscan2
- STRIP2 | c.1059C>T p.D353= | Silent (SNP) | VAF 79/382 reads (21%) | catalogued as rs1046028694; called by muse, mutect2, varscan2
- TAF11 | c.345G>A p.E115= | Silent (SNP) | VAF 54/190 reads (28%) | called by muse, mutect2, varscan2
- THBS2 | c.2364C>A p.I788= | Silent (SNP) | VAF 164/475 reads (35%) | called by muse, mutect2, varscan2
- TMCO4 | c.342G>A p.T114= | Silent (SNP) | VAF 77/159 reads (48%) | catalogued as rs201632654; called by muse, mutect2, varscan2
- TMEM69 | c.186G>A p.Q62= | Silent (SNP) | VAF 85/218 reads (39%) | catalogued as COSV63432342; called by muse, mutect2, varscan2
- TPO | c.1416C>A p.G472= | Silent (SNP) | VAF 190/804 reads (24%) | catalogued as COSV100221770; called by muse, mutect2, varscan2
- TRBJ2-5 | c.33G>A p.T11= | Silent (SNP) | VAF 175/798 reads (22%) | called by muse, mutect2, varscan2
- TREX1 | c.111G>A p.L37= (on ENST00000625293 / NM_033629.6; = p.L27= on NM_007248.5) | Silent (SNP) | VAF 197/557 reads (35%) | catalogued as rs1203330883; called by muse, mutect2, varscan2
- TRHDE | c.261C>T p.G87= | Silent (SNP) | VAF 195/631 reads (31%) | catalogued as rs768763758; called by muse, mutect2, varscan2
- TRIM42 | c.528C>T p.H176= | Silent (SNP) | VAF 152/482 reads (32%) | catalogued as COSV53883295; called by muse, mutect2, varscan2
- TTYH1 | c.498G>A p.T166= | Silent (SNP) | VAF 245/951 reads (26%) | catalogued as rs762808281, COSV100002018; called by muse, mutect2, varscan2
- VHLL | c.99G>A p.E33= | Silent (SNP) | VAF 145/575 reads (25%) | catalogued as COSV100372635; called by muse, mutect2, varscan2
- WT1 | c.279C>T p.G93= | Silent (SNP) | VAF 196/532 reads (37%) | called by muse, varscan2
- XKR5 | c.273G>A p.Q91= | Silent (SNP) | VAF 179/724 reads (25%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892647 G>A | 5'Flank (SNP) | VAF 151/397 reads (38%) | catalogued as rs1435662940; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415143 G>C | 5'Flank (SNP) | VAF 156/651 reads (24%) | called by muse, mutect2, varscan2
- NPAP1L | n.391A>C | RNA (SNP) | VAF 28/132 reads (21%) | catalogued as rs3884159; called by muse, mutect2
